Gene-level copy-number profile of tumor specimen TCGA-92-8063-01A from TCGA case TCGA-92-8063, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 52.5 years (19,193 days).
Specimen TCGA-92-8063-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a703f5ef-9c7f-413c-a1fe-c21d1718c651.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-92-8063-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ee0a526-78cf-4f65-a6dc-7cfc06fd5bf2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 19,287; copy number 2: 32,955; copy number 3: 6,618; copy number 4: 66; copy number 5: 584; copy number 6: 91; copy number 7: 33; copy number 8: 146; copy number 10: 16; copy number 11: 9; copy number 15: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-92-8063-01A-11D-2243-01): tumor purity 0.51, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:58,189,834–58,195,696, 1 gene: AC107896.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 749 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:82,754,012–83,162,930, 2 genes, copy number 10 (within-gene range 3–10): PCLO, RNA5SP235.
- chr7:84,847,877–85,489,293, 9 genes, copy number 11 (within-gene range 4–11): AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972.
- chr7:87,109,539–98,629,869, 188 genes, copy number 5–8 (broad region; genes not listed).
- chr7:98,989,867–106,286,326, 248 genes, copy number 5 (broad region; genes not listed).
- chr7:142,636,924–145,584,817, 128 genes, copy number 5 (broad region; genes not listed).
- chr7:150,433,654–159,233,377, 174 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
